Surgical pathology report (de-identified scan), TCGA case TCGA-WQ-A9G7, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site University of Kansas, specimen TCGA-WQ-A9G7-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

NAME:	SURG PATH #:
MR #:	SPECIMEN CLASS:
BILLING #:	ALT ID #:
LOCATION:	DATE OF PROCEDURE:
AGE:	DATE RECEIVED:
DOB:	TIME RECEIVED:
PHYSICIAN:	DATE OF REPORT:
COPY TO:	DATE OF PRINTING:

Material Received:

A: gallbladder
B: right hepatic lobectomy-tumor bank

History:

-year-old female with a right hepatic mass.

ICD-O-3
Carcinoma, hepatocellular NOS
8176/3
Site: Liver C22.0
6/13/14

Final Diagnosis:

- A. Gallbladder, "gallbladder", cholecystectomy:
Focal mild chronic inflammation.
- B. Liver, "right hepatic lobectomy-tumor bank", partial hepatectomy:
Poorly differentiated hepatocellular carcinoma. See comment.
Minimal steatosis (1%) and focal portal inflammation.

Comment:

Immunohistochemical studies are performed. The tumor cells are positive for glypican 3, CK7 (focal and weak), MOC-31 and they are negative for CK20, pCEA, and hepatocyte. Reticulin special stain shows loss of reticulin fiber.

Liver (Hepatectomy)-HCC

Specimen Type: Partial hepatectomy
Tumor Size: 12.0 x 11.0 x 9.0 cm and 1.1 x 0.8 x 0.8 cm
Tumor Focality: Multiple (2)
Histologic Type:
Hepatocellular carcinoma
Histologic Grade: GIII: Poorly differentiated
Tumor Extension: Tumor confined to liver
History of previous treatment (TACE or RFA): No
Treatment Effect: Not applicable
Margins: Assessed margins are uninvolved by carcinoma
Parenchymal Margin:
Uninvolved by invasive carcinoma
Vascular Invasion:
Macroscopic Venous (Large Vessel) Invasion (V): Not identified
Microscopic (Small Vessel) Invasion (L): Not identified
Lymph Nodes:
Number Examined: 0
Number Involved: 0

MR #:

Page 1 of 3

SURGICAL PATHOLOGY REPORT

Date of Printing:

Order Number:

[page 2 of 3]
NAME:
MR #:

SURG PATH #:
ALT ID #:

Additional Pathologic Findings: Minimal steatosis (1%) and focal portal inflammation.
Gross Picture Taken: No
Pathologic Staging: p3aNXMn/a

Primary Tumor (pT)

pT3a: Multiple tumors more than 5 cm

Regional Lymph Nodes (pN)

pNX: Cannot be assessed

Distant Metastasis (pM)

Not applicable

The pathologic stage assigned here should be regarded as provisional, as it reflects only current pathologic data and does not incorporate full knowledge of the patient's clinical status and/or prior pathology.

Pursuant to the _____ this case has been concurrently reviewed by the following
pathologist: _____ who agrees with the above diagnosis.

Attestation:

By this signature, I attest that I have personally formulated the final interpretation expressed in this report and that the above diagnosis is based upon my examination of the slides and/or other material indicated in this report.

Electronically Signed Out By

Interpreted by:

Gross Description:

A. Received in formalin, labeled with the patient's name and "gallbladder" is a 6.9 x 2.5 x 1.4 cm cholecystectomy specimen. The serosa is tan-purple and wrinkled. The gallbladder is opened to reveal a red-brown velvety mucosa with multiple yellow-gold flecks. No calculi are grossly identified within the gallbladder or accompanying specimen container. The gallbladder wall ranges in size from 0.2 to 0.4 cm. The cystic duct remnant contains a metallic staple and appears to be patent. Representative sections from the gallbladder body and fundus, and a shave of the cystic duct remnant (inked black) are submitted in cassette A1.

B. Received fresh labeled with the patient's name and "right hepatic lobectomy" is a partial hepatectomy specimen weighs 1180 grams and measures 20.0 x 13.5 x 9.1 cm in dimension. The external surface is tan-brown and glistening with a white tumor nodule measuring 0.8 x 0.8 x 0.8 cm. On the inferior surface, the serosa is focally bulging with an underlying mass. The area of firmness and protrusion measures 10.0 x 9.0 cm. The liver is serially sectioned at 0.5 cm intervals to reveal a smooth, glistening, tan-brown cut surface. There is a tan-yellow, well circumscribed and encapsulated mass measuring 12.0 x 11.0 x 9.0 cm in dimension and is 3.2cm from the parenchymal resection margin. The surface of the tumor is tan-yellow, firm with focal areas of hemorrhage. The mass extends to the inferior capsule of the right hepatic lobe. The perviously described nodule on the superior aspect of the liver upon sectioning measures 0.8 x 0.8 x 1.1 cm. Both the large described mass and smaller described mass are encapsulated and extend to the liver capsule.

- B1 Representative section of the vascular margin.
- B2 Representative section of the intrahepatic portal vein.
- B3 Representative section of grossly unremarkable hepatic tissue.
- B4 Tumor to inferior liver capsule (larger tumor).
- B5 Tumor to liver capsule (larger tumor).
- B6 Representative section of the smaller tumor to tumor capsule
- B7-B9 Representative sections of tumor to normal appearing hepatic tissue.
- B10 One possible lymph node, bisected.

If immunohistochemical stains and/or in situ hybridization are cited in this report, the performance characteristics were determined by the _____ in compliance with CLIA '88 regulations. Some of these tests rely on the use of "analyte specific reagents" and are subject to specific labeling requirements by the FDA.

MR #:

Page 2 of 3

Date of Printing:

SURGICAL PATHOLOGY REPORT

[page 3 of 3]
NAME:
MR #:

SURG PATH #:
ALT ID #:

Known positive and negative control tissues demonstrate appropriate staining. This testing was developed by the
It has not been cleared or approved by the FDA. The FDA has determined that such clearance
or approval is not necessary.

MR #:

Page 3 of 3

Date of Printing:

SURGICAL PATHOLOGY REPORT

Source: NCI Genomic Data Commons file 0f31de74-266a-4104-b8b9-94b62f0a98fb (TCGA-WQ-A9G7.211B2C4B-7DEB-4031-A3D2-5464A7386245.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).